Somatic mutation profile of tumor specimen MMRF_1777_1_BM_CD138pos (aliquot MMRF_1777_1_BM_CD138pos_T1_KBS5U_K11345) from MMRF case MMRF_1777, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 67.7 years (24,742 days).
Specimen MMRF_1777_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 431d45da-473e-4f87-9456-083d7d1b1ccc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1777_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1777_1_PB_Whole_C2_KBS5U_K11346; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7c386409-88f0-4aab-8cd7-41f8dbc25876

The open-access MAF lists 89 somatic variants for this specimen: 34 protein-altering or splice-affecting, 5 silent, 50 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, 3'UTR 29, Intron 12, Silent 5, 5'Flank 4, Splice Site 3, RNA 2, 5'UTR 2, Frame Shift Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 22/92 reads (24%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- AKR1C4 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 47/179 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.091); catalogued as COSV99578700; called by muse, mutect2, varscan2
- ATP9B | c.1031-1G>A p.X344_splice | Splice Site (SNP) | VAF 4/14 reads (29%) | catalogued as rs1568419451; called by muse, mutect2, varscan2
- C21orf62 | c.230A>G p.N77S | Missense Mutation (SNP) | VAF 46/215 reads (21%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs375363659; called by muse, mutect2, varscan2
- GLT8D2 | c.934C>T p.L312F | Missense Mutation (SNP) | VAF 51/190 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1159346634; called by muse, mutect2, varscan2
- IGHV3-7 | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 60/188 reads (32%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.353); catalogued as rs577702830; called by muse, varscan2
- MYT1L | c.1006G>A p.D336N | Missense Mutation (SNP) | VAF 79/228 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs951762938, COSV67725043; called by muse, mutect2, varscan2
- PODN | c.265G>A p.E89K (on ENST00000395871; = p.E41K on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.061); catalogued as rs113957899; called by muse, mutect2, varscan2
- PRTG | c.1055G>A p.G352E | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66838230; called by muse, mutect2, varscan2
- PTPRM | c.4105C>T p.R1369C | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as rs142668687; called by muse, mutect2, varscan2
- RNF133 | c.565C>T p.H189Y | Missense Mutation (SNP) | VAF 103/383 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.133); catalogued as rs755438406; called by muse, mutect2, varscan2
- SERPIND1 | c.817C>T p.L273F | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.88); catalogued as rs1437961176; called by muse, mutect2, varscan2
- TULP4 | c.2309C>T p.P770L | Missense Mutation (SNP) | VAF 48/96 reads (50%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.154); catalogued as rs1361729360; called by muse, mutect2, varscan2
- ZNF540 | c.1766G>A p.S589N | Missense Mutation (SNP) | VAF 40/165 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs1190063757; called by muse, mutect2, varscan2
- C4BPA | c.653C>A p.T218N | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- CACNA2D1 | c.780-1G>A p.X260_splice | Splice Site (SNP) | VAF 125/229 reads (55%) | called by muse, mutect2, varscan2
- CDH9 | c.1363A>T p.N455Y | Missense Mutation (SNP) | VAF 39/124 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDS1 | c.434T>A p.L145Q | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CYP4F3 | c.991G>T p.D331Y | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DCTN4 | c.603_607dup p.L203Pfs*14 | Frame Shift Ins (INS) | VAF 167/348 reads (48%) | called by mutect2, pindel, varscan2
- DMRTA2 | c.947C>A p.P316Q | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- FBLL1 | c.538G>A p.A180T | Missense Mutation (SNP) | VAF 34/142 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GAL3ST1 | c.1151A>C p.Q384P | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- HUWE1 | c.4042G>A p.A1348T | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- IGHV2-70D | c.304A>G p.T102A | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.062); called by muse, varscan2
- KNL1 | c.4549A>C p.K1517Q (on ENST00000346991 / NM_170589.5; = p.K1491Q on NM_144508.5) | Missense Mutation (SNP) | VAF 53/98 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- NOTCH2 | c.2407C>T p.P803S | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDH15 | c.4868A>C p.E1623A | Missense Mutation (SNP) | VAF 94/273 reads (34%) | SIFT tolerated, low confidence (0.16); called by muse, mutect2, varscan2
- PLA2G4D | c.1419G>C p.E473D | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.01); called by muse, mutect2
- RBMXL3 | c.1857C>G p.S619R | Missense Mutation (SNP) | VAF 53/162 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- RTL9 | c.648G>A p.M216I | Missense Mutation (SNP) | VAF 61/151 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SYNGAP1 | c.190-2A>C p.X64_splice | Splice Site (SNP) | VAF 62/115 reads (54%) | called by muse, mutect2, varscan2
- TMED9 | c.287T>G p.V96G | Missense Mutation (SNP) | VAF 37/200 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- TRAPPC9 | c.554A>G p.K185R | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.857); called by muse, mutect2
- ELSPBP1 | c.342C>T p.F114= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as COSV60413049; called by muse, mutect2, varscan2
- HGF | c.1365A>C p.G455= | Silent (SNP) | VAF 48/213 reads (23%) | called by muse, mutect2, varscan2
- IGHV2-70 | c.246A>G p.T82= | Silent (SNP) | VAF 21/92 reads (23%) | catalogued as rs367734033; called by muse, varscan2
- MROH2B | c.3954T>C p.T1318= | Silent (SNP) | VAF 12/67 reads (18%) | called by muse, mutect2, varscan2
- UCN3 | c.31C>T p.L11= | Silent (SNP) | VAF 61/169 reads (36%) | catalogued as rs782802876; called by muse, mutect2, varscan2
- AC244258.1 | n.425G>A | RNA (SNP) | VAF 37/142 reads (26%) | called by muse, mutect2, varscan2
- ALX4 | c.*3983G>A | 3'UTR (SNP) | VAF 33/103 reads (32%) | called by muse, mutect2, varscan2
- ARNT | c.956-31C>T | Intron (SNP) | VAF 18/78 reads (23%) | called by muse, mutect2, varscan2
- BTBD3 | c.*2863G>A | 3'UTR (SNP) | VAF 16/32 reads (50%) | called by muse, mutect2, varscan2
- CCR2 | c.*904A>G | 3'UTR (SNP) | VAF 18/56 reads (32%) | catalogued as rs891740602; called by muse, mutect2, varscan2
- CDK2AP2 | c.*85C>G | 3'UTR (SNP) | VAF 9/48 reads (19%) | called by muse, mutect2, varscan2
- CHST3 | c.*4006A>G | 3'UTR (SNP) | VAF 13/40 reads (33%) | catalogued as rs974678715; called by muse, mutect2, varscan2
- COPS2 | c.*2398T>C | 3'UTR (SNP) | VAF 20/149 reads (13%) | called by muse, mutect2, varscan2
- CSGALNACT1 | c.*875A>C | 3'UTR (SNP) | VAF 17/63 reads (27%) | catalogued as COSV59977401; called by muse, mutect2, varscan2
- DLG5 | c.*400G>T | 3'UTR (SNP) | VAF 36/97 reads (37%) | called by muse, mutect2, varscan2
- DNAAF3 | chr19:55166657 G>A | 5'Flank (SNP) | VAF 71/308 reads (23%) | catalogued as rs1282537937; called by muse, mutect2, varscan2
- EIF2AK3 | c.*701C>G | 3'UTR (SNP) | VAF 37/93 reads (40%) | called by muse, mutect2, varscan2
- FZD3 | c.*8818G>A | 3'UTR (SNP) | VAF 30/93 reads (32%) | called by muse, mutect2, varscan2
- GNA12 | c.*906C>T | 3'UTR (SNP) | VAF 40/150 reads (27%) | called by muse, mutect2, varscan2
- GRHPR | c.735-673A>T | Intron (SNP) | VAF 14/37 reads (38%) | called by muse, mutect2
- GTDC1 | c.*149G>T | 3'UTR (SNP) | VAF 13/32 reads (41%) | called by muse, mutect2, varscan2
- HNF4G | chr8:75566041 del A | 3'Flank (DEL) | VAF 16/46 reads (35%) | catalogued as rs577669664; called by mutect2, varscan2
- IDS | chrX:149505309 G>A | 5'Flank (SNP) | VAF 40/110 reads (36%) | called by muse, mutect2, varscan2
- IP6K1 | c.*2816C>T | 3'UTR (SNP) | VAF 22/70 reads (31%) | called by muse, varscan2
- ITGAV | c.*153C>T | 3'UTR (SNP) | VAF 31/95 reads (33%) | called by muse, mutect2, varscan2
- KIAA1755 | c.3+328G>C | Intron (SNP) | VAF 38/123 reads (31%) | called by muse, mutect2, varscan2
- KIF3A | c.*2469C>G | 3'UTR (SNP) | VAF 7/12 reads (58%) | called by muse, mutect2, varscan2
- KLHL34 | c.-401C>T | 5'UTR (SNP) | VAF 32/94 reads (34%) | called by muse, mutect2, varscan2
- MED28 | c.*871T>A | 3'UTR (SNP) | VAF 25/68 reads (37%) | called by muse, mutect2, varscan2
- MIR518A1 | n.79T>C | RNA (SNP) | VAF 22/67 reads (33%) | called by muse, mutect2, varscan2
- MITF | c.352-1219G>T | Intron (SNP) | VAF 88/278 reads (32%) | called by muse, mutect2, varscan2
- MTOR | c.5365-649C>A | Intron (SNP) | VAF 20/73 reads (27%) | called by muse, mutect2, varscan2
- NBEAL1 | c.*640G>C | 3'UTR (SNP) | VAF 13/44 reads (30%) | catalogued as rs1174256600; called by muse, mutect2, varscan2
- NRBF2 | c.*635A>G | 3'UTR (SNP) | VAF 19/61 reads (31%) | catalogued as rs953567330; called by muse, mutect2, varscan2
- NRBP2 | c.1437+16C>G | Intron (SNP) | VAF 10/38 reads (26%) | called by muse, mutect2, varscan2
- OBI1 | c.*331T>C | 3'UTR (SNP) | VAF 36/104 reads (35%) | called by muse, mutect2, varscan2
- POFUT2 | c.1137-351C>T | Intron (SNP) | VAF 19/129 reads (15%) | catalogued as rs956041977; called by muse, mutect2, varscan2
- PSMA2 | c.*422G>A | 3'UTR (SNP) | VAF 35/130 reads (27%) | called by muse, mutect2, varscan2
- RENBP | chrX:153944682 G>A | 5'Flank (SNP) | VAF 47/148 reads (32%) | called by muse, mutect2, varscan2
- RORA | c.197-60618G>A | Intron (SNP) | VAF 8/22 reads (36%) | called by muse, mutect2, varscan2
- RPA3 | c.*83C>G | 3'UTR (SNP) | VAF 43/144 reads (30%) | called by muse, mutect2, varscan2
- RWDD2B | c.*1560T>A | 3'UTR (SNP) | VAF 54/133 reads (41%) | called by muse, mutect2, varscan2
- SEMA3D | c.*2801C>T | 3'UTR (SNP) | VAF 21/118 reads (18%) | called by muse, mutect2, varscan2
- SGTB | c.*661A>C | 3'UTR (SNP) | VAF 45/170 reads (26%) | called by muse, mutect2, varscan2
- SPCS2 | c.*1047C>G | 3'UTR (SNP) | VAF 8/38 reads (21%) | called by muse, mutect2, varscan2
- SRGAP3 | c.1679-43C>T | Intron (SNP) | VAF 18/34 reads (53%) | called by muse, mutect2, varscan2
- SSBP4 | c.912+18G>C | Intron (SNP) | VAF 17/82 reads (21%) | called by muse, mutect2, varscan2
- TAGLN3 | c.*184T>G | 3'UTR (SNP) | VAF 16/67 reads (24%) | called by muse, varscan2
- TCF3 | c.1823-425G>A | Intron (SNP) | VAF 69/144 reads (48%) | catalogued as rs372813564; called by muse, mutect2, varscan2
- TEX35 | c.586+476C>G | Intron (SNP) | VAF 114/364 reads (31%) | called by muse, mutect2, varscan2
- UNC5D | c.*3747C>T | 3'UTR (SNP) | VAF 24/72 reads (33%) | catalogued as rs1266201239; called by muse, mutect2, varscan2
- UROD | chr1:45012167 C>A | 5'Flank (SNP) | VAF 14/39 reads (36%) | called by muse, mutect2, varscan2
- USP1 | c.*15C>T | 3'UTR (SNP) | VAF 36/116 reads (31%) | called by mutect2, varscan2
- ZNF704 | c.*8558C>A | 3'UTR (SNP) | VAF 35/92 reads (38%) | called by muse, mutect2, varscan2
- ZXDB | c.-347T>A | 5'UTR (SNP) | VAF 27/74 reads (36%) | called by muse, varscan2
